Somatic mutation profile of tumor specimen MMRF_1918_1_BM_CD138pos (aliquot MMRF_1918_1_BM_CD138pos_T1_KHS5U_L08073) from MMRF case MMRF_1918, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.5 years (20,629 days).
Specimen MMRF_1918_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 770df68a-73be-4209-ba5e-72ea97450f3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1918_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1918_1_PB_Whole_C2_KHS5U_L08074; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c30d06de-121f-4962-8763-770d73ac6e6d

The open-access MAF lists 87 somatic variants for this specimen: 36 protein-altering or splice-affecting, 14 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, 3'UTR 22, Silent 14, Intron 8, 5'UTR 4, Nonsense Mutation 3, 5'Flank 2, In Frame Del 1, Splice Site 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 51/133 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- AC008397.2 | c.251T>C p.L84P | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV53205490; called by muse, mutect2
- ACSM1 | c.1691T>C p.I564T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs142695037; called by muse, mutect2, varscan2
- ARHGEF10L | c.2893G>A p.V965M | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs372655907, COSV51429414; called by muse, mutect2, varscan2
- H1-4 | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1233751189, COSV56799690; called by muse, mutect2, varscan2
- IFIH1 | c.1757A>G p.E586G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as rs777933362, COSV55124899, COSV55126049; called by muse, mutect2, varscan2
- IGHJ4 | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 42/100 reads (42%) | PolyPhen benign (0.055); catalogued as rs545338481; called by muse, varscan2
- IGHV3-53 | c.215G>C p.S72T | Missense Mutation (SNP) | VAF 152/495 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as rs781938806; called by muse, mutect2, varscan2
- IGLV3-25 | c.155A>G p.Y52C | Missense Mutation (SNP) | VAF 94/150 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs375402708; called by muse, varscan2
- IMPG2 | c.1750C>G p.P584A | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs776220285; called by muse, mutect2, varscan2
- KRT86 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs748935718; called by mutect2, varscan2
- PTPRT | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1420220673, COSV62035828; called by muse, mutect2, varscan2
- SOCS1 | c.49G>C p.A17P | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV59659005, COSV59659365, COSV59661048; called by muse, mutect2, varscan2
- THSD7A | c.198G>A p.W66* | Nonsense Mutation (SNP) | VAF 43/115 reads (37%) | catalogued as rs765566337, COSV70272092; called by muse, mutect2, varscan2
- TRIM63 | c.1000A>G p.I334V | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs746481697; called by muse, mutect2, varscan2
- ZNF521 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.899); catalogued as rs1483368097, COSV64131109; called by muse, mutect2, varscan2
- ARRB1 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- B4GALNT4 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- C15orf62 | c.55A>C p.S19R | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- C2CD4D | c.962T>A p.L321Q | Missense Mutation (SNP) | VAF 119/229 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- C2CD4D | c.944_955del p.G315_R318del | In Frame Del (DEL) | VAF 100/224 reads (45%) | called by pindel, varscan2
- CD96 | c.776G>T p.S259I (on ENST00000283285 / NM_198196.3; = p.S243I on NM_005816.5) | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- COMMD9 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- DDX17 | c.38T>A p.L13* | Nonsense Mutation (SNP) | VAF 83/235 reads (35%) | called by muse, mutect2, varscan2
- DENND3 | c.1209G>A p.Q403= | Splice Region (SNP) | VAF 77/189 reads (41%) | called by muse, mutect2, varscan2
- DPP10 | c.1226A>C p.K409T | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FXR1 | c.1574A>C p.D525A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HAPLN1 | c.615_634del p.C205* | Nonsense Mutation (DEL) | VAF 32/119 reads (27%) | called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.146A>C p.D49A (on ENST00000354667 / NM_031243.3; = p.D37A on NM_002137.4) | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- HSP90B1 | c.1694T>G p.V565G | Missense Mutation (SNP) | VAF 87/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYOM2 | c.743-1G>C p.X248_splice | Splice Site (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- PCDHA7 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIPOR1 | c.2407G>A p.A803T (on ENST00000379312 / NM_001193522.2; = p.A799T on NM_024519.4) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- XRCC5 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP82 | c.514T>A p.C172S | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABL2 | c.2094T>C p.A698= (on ENST00000502732 / NM_007314.4; = p.A683= on NM_005158.5) | Silent (SNP) | VAF 63/167 reads (38%) | called by muse, mutect2, varscan2
- ALKBH8 | c.1038G>A p.P346= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs188523089; called by muse, mutect2, varscan2
- ARID3B | c.1290A>C p.S430= | Silent (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- EPC2 | c.1549T>C p.L517= | Silent (SNP) | VAF 132/284 reads (46%) | called by muse, mutect2, varscan2
- FNDC1 | c.1266G>T p.V422= | Silent (SNP) | VAF 49/113 reads (43%) | called by muse, mutect2, varscan2
- GRK1 | c.468C>T p.H156= | Silent (SNP) | VAF 38/89 reads (43%) | catalogued as rs1242479452; called by muse, mutect2, varscan2
- IGHJ4 | c.45A>C p.S15= | Silent (SNP) | VAF 64/135 reads (47%) | catalogued as rs141539541; called by muse, varscan2
- IGLV3-1 | c.294T>C p.A98= | Silent (SNP) | VAF 66/76 reads (87%) | catalogued as rs546240484; called by muse, varscan2
- KIF17 | c.918G>A p.T306= | Silent (SNP) | VAF 145/259 reads (56%) | catalogued as rs755200199; called by muse, mutect2, varscan2
- LRP1B | c.585T>A p.A195= | Silent (SNP) | VAF 50/121 reads (41%) | called by muse, mutect2, varscan2
- MAGEE2 | c.1005T>C p.D335= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- NID1 | c.2712C>T p.R904= | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV99937067; called by muse, mutect2, varscan2
- NOL9 | c.912T>G p.V304= | Silent (SNP) | VAF 110/269 reads (41%) | called by muse, mutect2, varscan2
- TP53BP2 | c.2064T>A p.S688= (on ENST00000343537 / NM_001031685.3; = p.S559= on NM_005426.2) | Silent (SNP) | VAF 31/105 reads (30%) | called by muse, mutect2, varscan2
- ABLIM3 | c.*458del | 3'UTR (DEL) | VAF 10/94 reads (11%) | called by mutect2, varscan2
- ACHE | c.*186C>A | 3'UTR (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- ANKEF1 | c.*415T>C | 3'UTR (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- ARRB1 | c.*829G>A | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- BCL7A | chr12:122021449 del ACTCTTTCCAAGAGCACCTCGCGTCCC | 5'Flank (DEL) | VAF 46/113 reads (41%) | called by mutect2, pindel, varscan2
- BMP6 | c.*1207A>T | 3'UTR (SNP) | VAF 61/140 reads (44%) | called by muse, mutect2, varscan2
- C7orf26 | c.1149-351T>C | Intron (SNP) | VAF 40/91 reads (44%) | called by muse, mutect2, varscan2
- C7orf26 | c.1149-350C>T | Intron (SNP) | VAF 38/89 reads (43%) | catalogued as rs1038321569; called by muse, mutect2, varscan2
- CCDC73 | c.429+1596A>T | Intron (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- CEP78 | c.*5888A>G | 3'UTR (SNP) | VAF 51/165 reads (31%) | called by muse, mutect2, varscan2
- GABRB3 | c.*321T>C | 3'UTR (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- GABRP | c.*911A>G | 3'UTR (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- LCMT1 | c.885-82T>G | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- LRP5L | n.443G>C | RNA (SNP) | VAF 58/153 reads (38%) | called by muse, mutect2, varscan2
- LYRM7 | c.*5426A>G | 3'UTR (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2
- MDS2 | chr1:23627096 C>G | 5'Flank (SNP) | VAF 31/82 reads (38%) | called by muse, mutect2, varscan2
- MME | c.*1479A>C | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2
- PGRMC2 | c.*1342G>C | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- POGLUT3 | c.203-133G>A | Intron (SNP) | VAF 83/173 reads (48%) | called by muse, mutect2, varscan2
- PPP1R18 | c.-433A>C | 5'UTR (SNP) | VAF 36/76 reads (47%) | called by muse, mutect2, varscan2
- PRDM13 | c.*226C>G | 3'UTR (SNP) | VAF 30/90 reads (33%) | called by muse, mutect2, varscan2
- RCVRN | c.*1368G>C | 3'UTR (SNP) | VAF 63/138 reads (46%) | called by muse, mutect2, varscan2
- RGS18 | c.*1213_*1218del | 3'UTR (DEL) | VAF 8/40 reads (20%) | called by mutect2, pindel, varscan2
- SAMD8 | c.-37G>A | 5'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- SAT2 | c.-99C>G | 5'UTR (SNP) | VAF 74/149 reads (50%) | called by muse, mutect2, varscan2
- SPTY2D1 | c.*2653G>A | 3'UTR (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- STARD5 | c.401-13C>T | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- STARD5 | c.401-14G>C | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- TNFRSF9 | c.*281C>T | 3'UTR (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- UTP23 | c.*1274A>G | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- VGLL3 | c.*1788del | 3'UTR (DEL) | VAF 41/126 reads (33%) | called by mutect2, pindel, varscan2
- VPS13A | c.*5093T>C | 3'UTR (SNP) | VAF 40/104 reads (38%) | called by muse, mutect2, varscan2
- ZCCHC10 | c.*1442_*1445del | 3'UTR (DEL) | VAF 19/107 reads (18%) | called by mutect2, pindel, varscan2
- ZNF266 | c.*82A>C | 3'UTR (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- ZNF407 | c.4877+22719C>A | Intron (SNP) | VAF 12/17 reads (71%) | called by muse, mutect2, varscan2
- ZNF772 | c.-112C>T | 5'UTR (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- ZNF831 | c.*1037T>G | 3'UTR (SNP) | VAF 32/75 reads (43%) | called by muse, mutect2, varscan2
